Somatic mutation profile of tumor specimen C3N-04280-03 (aliquot CPT0245600006) from CPTAC case C3N-04280, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage II; Tumor grade: G1; Age at diagnosis: 66.1 years (24,126 days).
Specimen C3N-04280-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d672918-08ad-4a44-9004-0a08bbae831d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-04280-31 (Blood Derived Normal), aliquot CPT0245620002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2dfe4f8a-3baa-4427-92a1-e3ceb08b426d

The open-access MAF lists 107 somatic variants for this specimen: 70 protein-altering or splice-affecting, 22 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 22, Intron 8, Nonsense Mutation 5, Splice Region 4, Frame Shift Del 3, 5'UTR 3, 3'UTR 3, Frame Shift Ins 2, In Frame Del 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 18/82 reads (22%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.1793G>T p.R598L | Missense Mutation (SNP) | VAF 125/505 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as COSV56859663; called by muse, mutect2, varscan2
- ADAMTS3 | c.2989G>T p.D997Y | Missense Mutation (SNP) | VAF 18/331 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54390481; called by muse, mutect2
- AFM | c.1056G>A p.A352= | Splice Region (SNP) | VAF 51/213 reads (24%) | catalogued as rs141061547; called by muse, mutect2, varscan2
- ANKRD36C | c.2561G>T p.R854L | Missense Mutation (SNP) | VAF 60/311 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.263); catalogued as COSV54756686, COSV99754816; called by muse, mutect2, varscan2
- ARHGEF33 | c.1891G>A p.E631K | Missense Mutation (SNP) | VAF 40/234 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.087); catalogued as rs1410680123; called by muse, mutect2, varscan2
- ASGR2 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 58/216 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.272); catalogued as rs534502192; called by muse, mutect2, varscan2
- AVPR1A | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 107/609 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100146920; called by muse, mutect2, varscan2
- BLNK | c.343G>T p.A115S | Missense Mutation (SNP) | VAF 77/261 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs140957683; called by muse, mutect2, varscan2
- C1QB | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 22/185 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1258691670, COSV59245068, COSV59246111; called by muse, mutect2, varscan2
- CCER1 | c.157C>T p.R53* | Nonsense Mutation (SNP) | VAF 84/392 reads (21%) | catalogued as rs775391790; called by muse, mutect2, varscan2
- CDH4 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 59/219 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs371477278; called by muse, mutect2, varscan2
- CDK5RAP1 | c.1112G>A p.R371H (on ENST00000357886 / NM_001365728.1; = p.R357H on NM_016082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/228 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745597149, COSV59428575, COSV59429089; called by muse, mutect2, varscan2
- CSMD2 | c.3287-4C>T | Splice Region (SNP) | VAF 16/56 reads (29%) | catalogued as COSV99587621; called by muse, mutect2
- DENND4A | c.967G>T p.D323Y | Missense Mutation (SNP) | VAF 62/265 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1432628650; called by muse, mutect2, varscan2
- DOK2 | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 39/454 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs779451507; called by muse, mutect2
- FBLN1 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 73/435 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774940379; called by muse, mutect2, varscan2
- FSIP2 | c.8337G>T p.L2779F | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100554001; called by muse, mutect2, varscan2
- FZD10 | c.1225G>A p.G409S | Missense Mutation (SNP) | VAF 138/314 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57475026; called by muse, mutect2, varscan2
- GUCY2C | c.2621C>T p.A874V | Missense Mutation (SNP) | VAF 85/187 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1156904184; called by muse, mutect2, varscan2
- GYPC | c.189A>T p.A63= | Splice Region (SNP) | VAF 95/375 reads (25%) | catalogued as COSV52145902, COSV52147915; called by muse, mutect2, varscan2
- IHH | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as rs771622789; called by muse, mutect2
- KREMEN2 | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 69/198 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.635); catalogued as rs1011887299; called by muse, mutect2, varscan2
- MRPL37 | c.168G>T p.E56D | Missense Mutation (SNP) | VAF 91/327 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.115); catalogued as COSV55277087; called by muse, mutect2, varscan2
- NCKAP1L | c.1018C>T p.R340W | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs764565874, COSV53203168; called by muse, mutect2
- NLRX1 | c.1672-2A>G p.X558_splice | Splice Site (SNP) | VAF 11/33 reads (33%) | catalogued as rs1311612464; called by muse, mutect2
- NME8 | c.881C>A p.A294D | Missense Mutation (SNP) | VAF 74/272 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV99553849, COSV99553898; called by muse, mutect2, varscan2
- OPRL1 | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 72/218 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as rs949887692, COSV61092232; called by muse, mutect2, varscan2
- PAQR9 | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 76/384 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as rs1451275285; called by muse, mutect2, varscan2
- POM121L12 | c.163del p.L55* | Frame Shift Del (DEL) | VAF 91/287 reads (32%) | catalogued as rs1349003029, COSV68693557; called by mutect2, pindel, varscan2
- PREX2 | c.1051G>C p.E351Q | Missense Mutation (SNP) | VAF 27/193 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.468); catalogued as COSV55784973; called by muse, mutect2, varscan2
- PXDNL | c.2558G>A p.R853Q | Missense Mutation (SNP) | VAF 211/403 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100685516, COSV100687207; called by muse, mutect2, varscan2
- SARDH | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 59/302 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs766945285, COSV53833543; called by muse, mutect2, varscan2
- SPATA16 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 49/138 reads (36%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs200483368, COSV63533586; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRIM42 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 49/310 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766965674, COSV53883946; called by muse, mutect2, varscan2
- WNT10B | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 20/542 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as COSV99975931; called by muse, mutect2
- ARFGEF1 | c.5127A>T p.A1709= | Splice Region (SNP) | VAF 18/110 reads (16%) | called by muse, mutect2
- C3orf20 | c.17G>A p.S6N | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.248); called by muse, varscan2
- CABIN1 | c.2811G>T p.E937D | Missense Mutation (SNP) | VAF 132/448 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- CR1L | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 48/377 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- EIF2AK4 | c.1456C>G p.L486V | Missense Mutation (SNP) | VAF 68/284 reads (24%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAT1 | c.8192_8193dup p.T2732Gfs*22 | Frame Shift Ins (INS) | VAF 54/174 reads (31%) | called by mutect2, pindel, varscan2
- FBL | c.386A>T p.D129V | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.038); called by muse, varscan2
- FOSL2 | c.596_602del p.R199Pfs*19 | Frame Shift Del (DEL) | VAF 114/233 reads (49%) | called by mutect2, pindel, varscan2
- GDF6 | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 52/241 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- GREM2 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 68/223 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GRWD1 | c.625T>C p.S209P | Missense Mutation (SNP) | VAF 17/598 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.127); called by muse, mutect2
- HCAR2 | c.289G>C p.D97H | Missense Mutation (SNP) | VAF 50/842 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- HCLS1 | c.436A>T p.K146* | Nonsense Mutation (SNP) | VAF 56/228 reads (25%) | called by muse, mutect2, varscan2
- HECW1 | c.1256C>A p.A419E | Missense Mutation (SNP) | VAF 109/393 reads (28%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0); called by muse, mutect2, varscan2
- JAG1 | c.3026A>T p.N1009I | Missense Mutation (SNP) | VAF 70/307 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- MAGEA3 | c.847T>A p.Y283N | Missense Mutation (SNP) | VAF 103/174 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- MTHFR | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 113/406 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- MUC12 | c.2014G>C p.G672R (on ENST00000379442; = p.G529R on NM_001164462.1) | Missense Mutation (SNP) | VAF 49/901 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- MYO18B | c.4466del p.G1489Efs*3 | Frame Shift Del (DEL) | VAF 42/201 reads (21%) | called by mutect2, pindel, varscan2
- NEDD1 | c.299C>T p.T100I | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- NEMF | c.520G>C p.V174L | Missense Mutation (SNP) | VAF 62/183 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NONO | c.998A>G p.E333G | Missense Mutation (SNP) | VAF 55/96 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- NOTCH1 | c.1149_1163del p.E383_C387del | In Frame Del (DEL) | VAF 239/559 reads (43%) | called by mutect2, pindel, varscan2
- OR2B2 | c.527A>G p.H176R | Missense Mutation (SNP) | VAF 82/147 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PAQR4 | c.220C>T p.Q74* | Nonsense Mutation (SNP) | VAF 16/507 reads (3%) | called by muse, mutect2
- PRAMEF20 | c.1089C>A p.D363E | Missense Mutation (SNP) | VAF 51/968 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2
- RIPK4 | c.532A>T p.M178L | Missense Mutation (SNP) | VAF 75/244 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SFI1 | c.2409G>C p.R803S (on ENST00000400288 / NM_001007467.3; = p.R772S on NM_014775.4) | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SLAIN2 | c.272T>A p.L91Q | Missense Mutation (SNP) | VAF 59/159 reads (37%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- SUCO | c.728dup p.N243Kfs*2 | Frame Shift Ins (INS) | VAF 10/69 reads (14%) | called by mutect2, pindel, varscan2
- TLN1 | c.1832C>T p.A611V | Missense Mutation (SNP) | VAF 30/428 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- VCAN | c.9620T>C p.I3207T | Missense Mutation (SNP) | VAF 68/265 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZFP36 | c.486C>A p.C162* (on ENST00000594442; = p.C156* on NM_003407.5) | Nonsense Mutation (SNP) | VAF 68/292 reads (23%) | called by muse, mutect2, varscan2
- ZNF567 | c.1150C>T p.Q384* (on ENST00000536254 / NM_001322913.1; = p.Q353* on NM_152603.5 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 61/229 reads (27%) | called by muse, mutect2, varscan2
- ADAMTS15 | c.1344C>T p.C448= | Silent (SNP) | VAF 60/249 reads (24%) | catalogued as rs376836072; called by muse, mutect2, varscan2
- AMPH | c.108C>T p.D36= | Silent (SNP) | VAF 51/277 reads (18%) | catalogued as rs770260327; called by muse, mutect2, varscan2
- C4A | c.2646G>A p.G882= | Silent (SNP) | VAF 264/753 reads (35%) | called by muse, mutect2, varscan2
- CBY2 | c.906C>T p.S302= | Silent (SNP) | VAF 18/106 reads (17%) | catalogued as COSV100137464; called by muse, mutect2, varscan2
- CCDC74B | c.612G>A p.A204= | Silent (SNP) | VAF 52/456 reads (11%) | catalogued as rs532714506; called by muse, mutect2, varscan2
- CCRL2 | c.204A>G p.G68= | Silent (SNP) | VAF 59/253 reads (23%) | called by muse, mutect2, varscan2
- CFAP70 | c.2085C>T p.A695= | Silent (SNP) | VAF 8/183 reads (4%) | called by muse, mutect2
- CHRNB2 | c.1257G>A p.P419= | Silent (SNP) | VAF 103/300 reads (34%) | catalogued as rs199743038; ClinVar: likely benign; called by muse, mutect2, varscan2
- COPS2 | c.951C>T p.A317= | Silent (SNP) | VAF 15/72 reads (21%) | called by muse, mutect2, varscan2
- CUX2 | c.1767C>T p.S589= | Silent (SNP) | VAF 86/558 reads (15%) | catalogued as rs201284456; called by muse, mutect2, varscan2
- DCC | c.4077G>A p.P1359= | Silent (SNP) | VAF 200/639 reads (31%) | catalogued as rs571287631, COSV71432561; called by muse, mutect2, varscan2
- FHL5 | c.315C>T p.C105= | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as COSV58736725; called by muse, varscan2
- PLPPR5 | c.837A>G p.A279= | Silent (SNP) | VAF 40/172 reads (23%) | called by muse, mutect2, varscan2
- SCT | c.165G>A p.G55= | Silent (SNP) | VAF 60/189 reads (32%) | catalogued as rs901895380; called by muse, mutect2, varscan2
- SDR16C5 | c.636A>G p.K212= | Silent (SNP) | VAF 51/283 reads (18%) | called by muse, mutect2, varscan2
- SLC18A1 | c.60G>T p.R20= | Silent (SNP) | VAF 72/292 reads (25%) | called by muse, mutect2, varscan2
- SPTBN2 | c.945G>A p.S315= | Silent (SNP) | VAF 128/436 reads (29%) | catalogued as rs758056414, COSV59450972; ClinVar: likely benign; called by muse, mutect2, varscan2
- SS18L1 | c.861G>T p.T287= | Silent (SNP) | VAF 67/217 reads (31%) | called by muse, mutect2, varscan2
- TMEM47 | c.108G>C p.G36= | Silent (SNP) | VAF 91/141 reads (65%) | called by muse, mutect2, varscan2
- TPH1 | c.447G>A p.A149= | Silent (SNP) | VAF 24/198 reads (12%) | catalogued as rs369502060; called by muse, mutect2, varscan2
- ZNF222 | c.204C>A p.S68= | Silent (SNP) | VAF 12/148 reads (8%) | catalogued as COSV99496192; called by muse, mutect2
- ZSWIM9 | c.1617T>C p.G539= | Silent (SNP) | VAF 3/17 reads (18%) | called by muse, mutect2
- AC116366.2 | c.-637-10377G>C | Intron (SNP) | VAF 124/451 reads (27%) | called by muse, mutect2, varscan2
- C3 | c.599+37C>A | Intron (SNP) | VAF 175/568 reads (31%) | called by muse, mutect2, varscan2
- CAPN3 | c.1914+31C>A | Intron (SNP) | VAF 147/503 reads (29%) | called by muse, mutect2, varscan2
- CLUHP11 | n.788T>C | RNA (SNP) | VAF 65/223 reads (29%) | called by muse, mutect2, varscan2
- COX7A1 | c.*1G>A | 3'UTR (SNP) | VAF 9/287 reads (3%) | called by muse, mutect2
- FAM86B1 | c.241-1242G>A | Intron (SNP) | VAF 58/394 reads (15%) | called by muse, mutect2, varscan2
- HLA-DQA1 | c.82+1402_82+1413delinsTGGACAGTG | Intron (DEL) | VAF 7/43 reads (16%) | called by pindel, varscan2*
- NRP2 | c.2440+9654G>A | Intron (SNP) | VAF 99/420 reads (24%) | catalogued as rs768540716, COSV99783231; called by muse, mutect2, varscan2
- PAX6 | c.10+46G>T | Intron (SNP) | VAF 57/187 reads (30%) | called by muse, mutect2, varscan2
- REPS1 | c.*28T>C | 3'UTR (SNP) | VAF 13/109 reads (12%) | called by muse, mutect2, varscan2
- RGS6 | c.*247G>C | 3'UTR (SNP) | VAF 41/167 reads (25%) | called by muse, mutect2, varscan2
- SERPINB13 | c.473-148G>T | Intron (SNP) | VAF 34/277 reads (12%) | catalogued as rs1385052889; called by muse, mutect2, varscan2
- TERT | c.-64G>A | 5'UTR (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2, varscan2
- TERT | c.-65C>G | 5'UTR (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- ZIC3 | c.-9G>A | 5'UTR (SNP) | VAF 16/161 reads (10%) | catalogued as rs1463513689; called by muse, mutect2, varscan2
